Surgical pathology report (de-identified scan), TCGA case TCGA-06-0168, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0168-01A (Primary Tumor).

TCGA-06-0168

PATH. NO:

NAME:

MED. REC. NO:

AGE/SEX:

SURGERY DATE:

PATIENT PHONE NO.:

RECEIVE DATE:

PHYSICIAN:

COPY TO:

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN BIOPSY, GLIOBLASTOMA MULTIFORME. MIB-1: ABOUT 30%
B. BRAIN BIOPSY, GLIOBLASTOMA MULTIFORME.

Operation/Specimen: A. Sent for FS. B. Brain tumor perm.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY:

- A. Multiple 0.2-0.6 cm tissue fragments. Frozen section
diagnosis: glioma, adenocarcinoma submitted in 1,2.
B.
SPECIMEN: Brain tumor permanent.
FIXATIVE: None.
GENERAL: 2.5 x 2.5 x 1.3 cm. in aggregate. There are multiple
areas of red clotted blood.
SECTIONS: 3-4 - all submitted.
[REDACTED]

MICROSCOPIC: A,B. Sections show a high grade glioma with
hypercellularity, frequent mitotic figures, vascular hyperplasia and
multiple foci of necrosis.
[REDACTED]
[REDACTED]

TISSUE COMMITTEE CODE: [REDACTED]

ICD9: 191

BILLING CODES: [REDACTED]

Source: NCI Genomic Data Commons file 247af914-444d-46b0-91a8-21bc5eae9015 (TCGA-06-0168.204CC10B-2024-400F-BCAA-161955D0F3B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).